Somatic mutation profile of tumor specimen TARGET-10-PATPWF-03A (aliquot TARGET-10-PATPWF-03A-01D) from TARGET case TARGET-10-PATPWF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (661 days).
Specimen TARGET-10-PATPWF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6f2465f-3162-4cda-9f94-78074b89a182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATPWF-10A (Blood Derived Normal), aliquot TARGET-10-PATPWF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8d771d5-9345-4a50-af8b-431fb4bcd23c

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL14A1 | c.4295G>T p.C1432F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52865612; called by muse, mutect2, varscan2
- ENPP1 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as rs536779694, COSV62935501; called by muse, mutect2, varscan2
- KLHL1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as COSV100916933; called by muse, mutect2
- MUC5B | c.5623C>T p.R1875C | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71594694; called by muse, mutect2, varscan2
- NIM1K | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs1318206375, COSV58139059; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>A p.L1600Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- TACC2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199400051, COSV57755723; called by muse, mutect2, varscan2
- F8 | c.4841dup p.D1615Gfs*10 | Frame Shift Ins (INS) | VAF 27/47 reads (57%) | called by mutect2, pindel, varscan2
- KIR3DX1 | n.615G>A | RNA (SNP) | VAF 24/49 reads (49%) | catalogued as rs766261140, COSV55600052; called by muse, mutect2, varscan2
